Somatic mutation profile of tumor specimen TCGA-AX-A1CF-01A (aliquot TCGA-AX-A1CF-01A-11D-A135-09) from TCGA case TCGA-AX-A1CF, project TCGA-UCEC (Uterine Corpus Endometrial Carcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Endometrioid adenocarcinoma, NOS; Tissue or organ of origin: Endometrium; FIGO stage: Stage IVB; Tumor grade: G3; Age at diagnosis: 69.3 years (25,300 days).
Specimen TCGA-AX-A1CF-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) ec67c947-0569-45ff-9a10-aef4c1a43329.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-AX-A1CF-11A (Solid Tissue Normal), aliquot TCGA-AX-A1CF-11A-11D-A135-09; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/5e60147c-26da-44e8-b9f6-e9d37070ba3d

The open-access MAF lists 121 somatic variants for this specimen: 93 protein-altering or splice-affecting, 25 silent, 3 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 76, Silent 25, Frame Shift Del 10, Splice Site 4, Nonsense Mutation 3, Intron 1, 3'UTR 1, RNA 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- TP53 | c.836G>A p.G279E | Missense Mutation (SNP) | VAF 9/18 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1064793881, COSV52677880, COSV52851240; ClinVar: uncertain significance / likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- ACTR3B | c.839A>G p.E280G | Missense Mutation (SNP) | VAF 32/78 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.917); catalogued as COSV99753475; called by muse, mutect2, varscan2
- ANKRD50 | c.4250C>T p.S1417F | Missense Mutation (SNP) | VAF 38/59 reads (64%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.226); catalogued as rs774247434, COSV101538867; called by muse, mutect2, varscan2
- ANXA2R | c.275G>T p.S92I | Missense Mutation (SNP) | VAF 27/62 reads (44%) | SIFT tolerated (0.42); PolyPhen benign (0.01); catalogued as COSV100148600; called by muse, mutect2, varscan2
- APBB2 | c.1333A>T p.N445Y (on ENST00000295974 / NM_001166050.2; = p.N446Y on NM_004307.2) | Missense Mutation (SNP) | VAF 41/119 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99922263; called by muse, mutect2, varscan2
- ARSJ | c.1784G>T p.G595V | Missense Mutation (SNP) | VAF 11/13 reads (85%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.015); catalogued as COSV100192358; called by muse, mutect2, varscan2
- AXL | c.1176G>C p.E392D | Missense Mutation (SNP) | VAF 17/48 reads (35%) | SIFT tolerated (0.12); PolyPhen benign (0.341); catalogued as COSV99995719; called by muse, mutect2, varscan2
- B3GNT5 | c.835C>G p.L279V | Missense Mutation (SNP) | VAF 5/53 reads (9%) | SIFT deleterious (0.01); PolyPhen benign (0.273); catalogued as COSV100190937; called by muse, mutect2
- BPI | c.671T>G p.L224R (on ENST00000262865; = p.L220R on NM_001725.3) | Missense Mutation (SNP) | VAF 16/43 reads (37%) | SIFT deleterious (0); PolyPhen possibly damaging (0.811); catalogued as COSV99480310; called by muse, mutect2, varscan2
- BUB1B | c.2980A>C p.N994H | Missense Mutation (SNP) | VAF 20/31 reads (65%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.781); catalogued as COSV99806438; called by muse, mutect2, varscan2
- C7 | c.653C>G p.S218C | Missense Mutation (SNP) | VAF 16/36 reads (44%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.62); catalogued as rs1412705418, COSV100495241; called by muse, mutect2, varscan2
- CBLN2 | c.296G>A p.R99Q | Missense Mutation (SNP) | VAF 17/35 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99504066, COSV99504089; called by muse, mutect2, varscan2
- CKAP2 | c.1072G>C p.A358P (on ENST00000378037 / NM_001098525.2; = p.A357P on NM_018204.5) | Missense Mutation (SNP) | VAF 12/15 reads (80%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.804); catalogued as rs750786244, COSV99318012, COSV99318481; called by muse, mutect2, varscan2
- CRYBB1 | c.418C>T p.R140W | Missense Mutation (SNP) | VAF 17/49 reads (35%) | SIFT deleterious (0.04); PolyPhen probably damaging (1); catalogued as COSV99315798; called by muse, mutect2, varscan2
- CSMD3 | c.10168A>T p.T3390S (on ENST00000297405 / NM_001363185.1; = p.T3221S on NM_052900.3) | Missense Mutation (SNP) | VAF 40/108 reads (37%) | SIFT tolerated (0.16); PolyPhen benign (0.012); catalogued as COSV99821379; called by muse, mutect2, varscan2
- CUBN | c.2647G>C p.G883R | Missense Mutation (SNP) | VAF 26/76 reads (34%) | SIFT deleterious (0.02); PolyPhen benign (0.173); catalogued as COSV100911900; called by muse, mutect2, varscan2
- DDX19B | c.201A>C p.R67S | Missense Mutation (SNP) | VAF 22/49 reads (45%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.941); catalogued as COSV99849737; called by muse, mutect2, varscan2
- DHRS9 | c.193G>C p.G65R | Missense Mutation (SNP) | VAF 29/69 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as COSV100513294; called by muse, mutect2, varscan2
- DNAH9 | c.6164G>C p.G2055A | Missense Mutation (SNP) | VAF 15/20 reads (75%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV52347411, COSV99303230; called by muse, mutect2, varscan2
- DOK5 | c.546C>A p.S182R | Missense Mutation (SNP) | VAF 20/229 reads (9%) | SIFT tolerated (0.23); PolyPhen possibly damaging (0.888); catalogued as COSV52821554, COSV99373081; called by muse, mutect2
- DST | c.20272A>G p.R6758G (on ENST00000361203 / NM_001374722.1; = p.R4455G on NM_015548.5) | Missense Mutation (SNP) | VAF 7/20 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV99749711; called by muse, mutect2, varscan2
- DUSP1 | c.791G>T p.R264L | Missense Mutation (SNP) | VAF 9/12 reads (75%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1219325819, COSV99495822; called by muse, mutect2, varscan2
- DYNC1H1 | c.13060G>A p.D4354N | Missense Mutation (SNP) | VAF 4/12 reads (33%) | SIFT deleterious (0.04); PolyPhen benign (0.31); catalogued as rs1449580462, COSV100794204; called by mutect2, varscan2
- EBF1 | c.733C>T p.R245W | Missense Mutation (SNP) | VAF 17/25 reads (68%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV100564972; called by muse, mutect2, varscan2
- FAM135B | c.3749A>G p.H1250R | Missense Mutation (SNP) | VAF 99/113 reads (88%) | SIFT deleterious (0); PolyPhen probably damaging (0.977); catalogued as COSV99417473; called by muse, mutect2, varscan2
- FAM187B | c.1087A>C p.T363P | Missense Mutation (SNP) | VAF 12/27 reads (44%) | SIFT tolerated (0.08); PolyPhen benign (0); catalogued as COSV100219927; called by muse, mutect2, varscan2
- FER1L6 | c.5288C>G p.T1763R | Missense Mutation (SNP) | VAF 8/81 reads (10%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.999); catalogued as COSV101205277; called by muse, mutect2
- FIGNL1 | c.1621G>C p.V541L | Missense Mutation (SNP) | VAF 13/40 reads (33%) | SIFT tolerated (0.07); PolyPhen benign (0.399); catalogued as COSV100794812; called by muse, mutect2, varscan2
- FIGNL1 | c.1049del p.G350Efs*27 | Frame Shift Del (DEL) | VAF 20/74 reads (27%) | catalogued as COSV100794899; called by mutect2, pindel, varscan2
- FRAS1 | c.11667G>C p.E3889D | Missense Mutation (SNP) | VAF 23/32 reads (72%) | SIFT tolerated (0.27); PolyPhen benign (0.015); catalogued as rs1189186784, COSV99347256; called by muse, mutect2, varscan2
- GK2 | c.1124G>C p.S375T | Missense Mutation (SNP) | VAF 34/59 reads (58%) | SIFT tolerated (0.05); PolyPhen benign (0.026); catalogued as COSV100725842; called by muse, mutect2, varscan2
- GLOD4 | c.286A>G p.K96E (on ENST00000301328 / NM_001366247.1; = p.K81E on NM_016080.3 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 32/58 reads (55%) | SIFT tolerated (0.67); PolyPhen benign (0.003); catalogued as COSV100022373; called by muse, mutect2, varscan2
- GRHL2 | c.825C>G p.F275L | Missense Mutation (SNP) | VAF 27/89 reads (30%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV99305833; called by muse, mutect2, varscan2
- H4C2 | c.137G>T p.R46L | Missense Mutation (SNP) | VAF 12/75 reads (16%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.919); catalogued as COSV55138254, COSV99774715, COSV99774982; called by muse, mutect2, varscan2
- HYAL2 | c.1396G>C p.A466P | Missense Mutation (SNP) | VAF 9/22 reads (41%) | SIFT tolerated (0.26); PolyPhen possibly damaging (0.48); catalogued as COSV100753797; called by muse, mutect2, varscan2
- KCTD16 | c.1048C>T p.P350S | Missense Mutation (SNP) | VAF 9/11 reads (82%) | SIFT tolerated (0.09); PolyPhen benign (0.003); catalogued as COSV101568688, COSV72578773; called by muse, mutect2, varscan2
- KCTD20 | c.193A>G p.N65D | Missense Mutation (SNP) | VAF 29/129 reads (22%) | SIFT tolerated, low confidence (0.09); PolyPhen benign (0.01); catalogued as rs777863461, COSV99535705; called by muse, mutect2, varscan2
- KIZ | c.1394T>A p.V465E | Missense Mutation (SNP) | VAF 97/301 reads (32%) | SIFT deleterious (0.01); PolyPhen benign (0.082); catalogued as COSV99851781; called by muse, mutect2, varscan2
- KLHL38 | c.689C>G p.A230G | Missense Mutation (SNP) | VAF 7/35 reads (20%) | SIFT deleterious (0.05); PolyPhen benign (0.026); catalogued as rs1233251901, COSV100384207; called by muse, mutect2, varscan2
- KMT2A | c.11059G>C p.E3687Q | Missense Mutation (SNP) | VAF 11/31 reads (35%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.998); catalogued as COSV100627649, COSV63290487; called by muse, mutect2, varscan2
- LAMA1 | c.2038A>C p.M680L | Missense Mutation (SNP) | VAF 29/74 reads (39%) | SIFT tolerated (0.2); PolyPhen benign (0.011); catalogued as COSV101054594; called by muse, mutect2, varscan2
- LGALS3BP | c.1110G>C p.E370D | Missense Mutation (SNP) | VAF 7/23 reads (30%) | SIFT deleterious (0.01); PolyPhen benign (0.031); catalogued as COSV99431270; called by muse, mutect2, varscan2
- LILRA5 | c.878C>A p.P293H | Missense Mutation (SNP) | VAF 15/44 reads (34%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.535); catalogued as COSV100006662; called by muse, mutect2, varscan2
- LYST | c.7880G>C p.S2627T | Missense Mutation (SNP) | VAF 63/139 reads (45%) | SIFT tolerated (0.13); PolyPhen probably damaging (0.997); catalogued as COSV101087818; called by muse, mutect2, varscan2
- MON2 | c.3457G>T p.A1153S | Missense Mutation (SNP) | VAF 24/47 reads (51%) | SIFT tolerated (0.57); PolyPhen benign (0.355); catalogued as rs1218488613, COSV99741339; called by muse, mutect2, varscan2
- MRPS15 | c.163G>C p.V55L | Missense Mutation (SNP) | VAF 8/24 reads (33%) | SIFT tolerated (0.4); PolyPhen benign (0); catalogued as COSV100117157; called by muse, mutect2, varscan2
- MYO15A | c.1169A>C p.E390A | Missense Mutation (SNP) | VAF 4/12 reads (33%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.037); catalogued as COSV99230715; called by mutect2, varscan2
- NEK1 | c.3124G>T p.A1042S | Missense Mutation (SNP) | VAF 13/67 reads (19%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.887); catalogued as COSV101455581, COSV71458182; called by muse, mutect2, varscan2
- NEO1 | c.2364C>G p.D788E | Missense Mutation (SNP) | VAF 41/87 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV99981104; called by muse, mutect2, varscan2
- NRG3 | c.1323G>C p.E441D | Missense Mutation (SNP) | VAF 24/59 reads (41%) | SIFT tolerated (0.25); PolyPhen benign (0.02); catalogued as COSV100930359, COSV100932687; called by muse, mutect2, varscan2
- OR5H2 | c.665C>T p.S222F | Missense Mutation (SNP) | VAF 26/88 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100788591, COSV62350172, COSV62350867; called by muse, mutect2, varscan2
- OR9G4 | c.445T>G p.Y149D | Missense Mutation (SNP) | VAF 13/44 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs994092939, COSV100264963; called by muse, mutect2, varscan2
- OTUD7B | c.632T>A p.L211* | Nonsense Mutation (SNP) | VAF 26/76 reads (34%) | catalogued as COSV100967310; called by muse, mutect2, varscan2
- PARP14 | c.3840G>T p.Q1280H | Missense Mutation (SNP) | VAF 18/62 reads (29%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.976); catalogued as COSV101506210; called by muse, mutect2, varscan2
- PDCD11 | c.1976A>G p.N659S | Missense Mutation (SNP) | VAF 34/97 reads (35%) | SIFT tolerated (0.18); PolyPhen benign (0.007); catalogued as COSV100874214; called by muse, mutect2, varscan2
- PEG3 | c.232G>C p.E78Q | Missense Mutation (SNP) | VAF 20/46 reads (43%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.745); catalogued as COSV99686731; called by muse, mutect2, varscan2
- PITPNM2 | c.3423G>C p.Q1141H | Missense Mutation (SNP) | VAF 5/13 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV99758090; called by muse, mutect2, varscan2
- PLD2 | c.2441G>A p.S814N | Missense Mutation (SNP) | VAF 19/54 reads (35%) | SIFT tolerated (0.07); PolyPhen benign (0.046); catalogued as COSV99561972; called by muse, mutect2, varscan2
- PLXND1 | c.4586C>T p.S1529F | Missense Mutation (SNP) | VAF 8/38 reads (21%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.999); catalogued as COSV100138848; called by mutect2, varscan2
- POLE | c.5472G>T p.W1824C | Missense Mutation (SNP) | VAF 27/98 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100265046; called by muse, mutect2, varscan2
- PROX1 | c.472T>A p.C158S | Missense Mutation (SNP) | VAF 17/21 reads (81%) | SIFT tolerated (0.52); PolyPhen benign (0.003); catalogued as COSV99798511; called by muse, mutect2, varscan2
- RING1 | c.855G>C p.K285N | Missense Mutation (SNP) | VAF 15/55 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); catalogued as COSV100761706; called by muse, mutect2, varscan2
- ROR1 | c.2149T>C p.C717R | Missense Mutation (SNP) | VAF 31/54 reads (57%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100934783; called by muse, mutect2, varscan2
- SERPINA1 | c.1126T>G p.F376V | Missense Mutation (SNP) | VAF 16/55 reads (29%) | SIFT tolerated (0.75); PolyPhen benign (0); catalogued as COSV100871962, COSV63346590; called by muse, mutect2, varscan2
- SERPINE1 | c.154G>T p.D52Y | Missense Mutation (SNP) | VAF 19/44 reads (43%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as COSV99776523; called by muse, mutect2, varscan2
- SLC27A4 | c.1250G>A p.R417Q | Missense Mutation (SNP) | VAF 8/16 reads (50%) | SIFT tolerated (0.12); PolyPhen benign (0.284); catalogued as rs778672007, COSV100306967; called by muse, mutect2, varscan2
- SLC41A3 | c.910A>G p.S304G | Missense Mutation (SNP) | VAF 52/148 reads (35%) | SIFT tolerated (0.06); PolyPhen benign (0.114); catalogued as rs1286144045, COSV100259285; called by muse, mutect2, varscan2
- SLC6A12 | c.1147C>G p.L383V | Missense Mutation (SNP) | VAF 10/19 reads (53%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.931); catalogued as COSV100674964; called by muse, mutect2, varscan2
- SMARCA4 | c.2982C>G p.Y994* | Nonsense Mutation (SNP) | VAF 8/11 reads (73%) | catalogued as COSV100758016, COSV60809406; called by muse, mutect2, varscan2
- SORCS3 | c.3364C>A p.H1122N | Missense Mutation (SNP) | VAF 6/136 reads (4%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.917); catalogued as COSV100864284; called by muse, mutect2
- SPAG1 | c.489-1G>C p.X163_splice | Splice Site (SNP) | VAF 6/64 reads (9%) | catalogued as COSV52559219, COSV99308267; called by muse, mutect2
- STK39 | c.859C>G p.Q287E | Missense Mutation (SNP) | VAF 27/75 reads (36%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.46); catalogued as COSV100596186; called by muse, mutect2, varscan2
- SYNE2 | c.534A>C p.R178S | Missense Mutation (SNP) | VAF 40/105 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.921); catalogued as COSV100419985; called by muse, mutect2, varscan2
- TMEM131 | c.3965C>A p.S1322Y | Missense Mutation (SNP) | VAF 8/16 reads (50%) | SIFT tolerated, low confidence (0.37); PolyPhen benign (0.178); catalogued as COSV99486181; called by muse, mutect2
- TNXB | c.10124T>A p.L3375Q (on ENST00000647633; = p.L3128Q on NM_019105.8 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 11/43 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.978); catalogued as COSV100925677; called by muse, mutect2, varscan2
- TOX2 | c.219C>G p.N73K (on ENST00000358131 / NM_001098798.2; = p.N22K on NM_032883.3) | Missense Mutation (SNP) | VAF 28/65 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.928); catalogued as COSV100363184, COSV57885768; called by muse, mutect2, varscan2
- TRIM36 | c.806G>A p.G269D | Missense Mutation (SNP) | VAF 50/66 reads (76%) | SIFT tolerated (0.17); PolyPhen benign (0.007); catalogued as rs769924762, COSV99142225; called by muse, mutect2, varscan2
- UHRF1BP1 | c.2609G>C p.C870S | Missense Mutation (SNP) | VAF 5/26 reads (19%) | SIFT deleterious (0.04); PolyPhen benign (0.123); catalogued as COSV99511317; called by muse, mutect2, varscan2
- ZNF624 | c.82C>T p.R28C | Missense Mutation (SNP) | VAF 26/31 reads (84%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.057); catalogued as rs143880448; called by muse, mutect2, varscan2
- ANK3 | c.1882_1887+20del p.X628_splice | Splice Site (DEL) | VAF 21/81 reads (26%) | called by mutect2, pindel, varscan2
- ARHGAP33 | c.981_982+23del p.X327_splice | Splice Site (DEL) | VAF 14/18 reads (78%) | called by mutect2, varscan2
- B2M | c.43_44del p.L15Ffs*41 | Frame Shift Del (DEL) | VAF 13/25 reads (52%) | called by pindel, varscan2
- BCL9L | c.1895_1914del p.P632Lfs*27 | Frame Shift Del (DEL) | VAF 11/26 reads (42%) | called by mutect2, pindel, varscan2
- CEP192 | c.6644del p.H2215Pfs*10 | Frame Shift Del (DEL) | VAF 32/92 reads (35%) | called by mutect2, varscan2
- ERAS | c.593_618del p.E198Gfs*10 | Frame Shift Del (DEL) | VAF 10/18 reads (56%) | called by mutect2, pindel, varscan2
- GGPS1 | c.218_230del p.R73Qfs*28 | Frame Shift Del (DEL) | VAF 31/83 reads (37%) | called by mutect2, pindel, varscan2
- HNMT | c.300del p.E100Dfs*3 | Frame Shift Del (DEL) | VAF 6/54 reads (11%) | called by mutect2, varscan2
- KIT | c.620-19_635del p.X207_splice | Splice Site (DEL) | VAF 16/37 reads (43%) | called by mutect2, pindel, varscan2
- LRFN2 | c.480_485delinsTC p.H162Afs*16 | Frame Shift Del (DEL) | VAF 10/29 reads (34%) | called by pindel, varscan2*
- PGM1 | c.699_715delinsGT p.K234_E239delins* | Nonsense Mutation (DEL) | VAF 46/81 reads (57%) | called by pindel, varscan2*
- TBCE | c.340_352del p.I114Lfs*3 | Frame Shift Del (DEL) | VAF 6/66 reads (9%) | called by mutect2, pindel
- TRPM1 | c.4401_4417del p.T1468Sfs*9 | Frame Shift Del (DEL) | VAF 45/79 reads (57%) | called by mutect2, pindel, varscan2
- VEPH1 | c.1366C>G p.L456V | Missense Mutation (SNP) | VAF 3/44 reads (7%) | SIFT tolerated (0.51); PolyPhen benign (0.137); called by muse, mutect2
- ANKMY1 | c.1536C>A p.T512= | Silent (SNP) | VAF 12/17 reads (71%) | catalogued as rs937084312, COSV99800994; called by muse, mutect2, varscan2
- AOC3 | c.667C>A p.R223= | Silent (SNP) | VAF 30/37 reads (81%) | catalogued as COSV53826968, COSV99519883; called by muse, mutect2, varscan2
- APOL3 | c.939A>C p.R313= (on ENST00000349314 / NM_145640.2; = p.R242= on NM_014349.3 and 2 other RefSeq transcripts) | Silent (SNP) | VAF 18/43 reads (42%) | catalogued as COSV100651949; called by muse, mutect2, varscan2
- CAPN13 | c.6G>A p.A2= | Silent (SNP) | VAF 16/43 reads (37%) | catalogued as rs377311890; called by muse, mutect2, varscan2
- EDN2 | c.78T>G p.A26= | Silent (SNP) | VAF 23/89 reads (26%) | catalogued as COSV101006301; called by muse, mutect2, varscan2
- EP400 | c.240C>A p.G80= | Silent (SNP) | VAF 20/25 reads (80%) | catalogued as COSV100200111; called by muse, mutect2, varscan2
- FBXO8 | c.21A>G p.R7= | Silent (SNP) | VAF 27/86 reads (31%) | catalogued as rs369540951; called by muse, mutect2, varscan2
- H4C5 | c.105C>T p.I35= | Silent (SNP) | VAF 41/75 reads (55%) | catalogued as rs571073582, COSV100747843; called by muse, mutect2, varscan2
- HKDC1 | c.264C>A p.S88= | Silent (SNP) | VAF 13/37 reads (35%) | catalogued as COSV100664316; called by muse, mutect2, varscan2
- KIAA1755 | c.3471C>G p.T1157= | Silent (SNP) | VAF 7/26 reads (27%) | catalogued as rs758624759, COSV99641323; called by muse, mutect2, varscan2
- KIR3DL2 | c.6G>T p.S2= | Silent (SNP) | VAF 18/66 reads (27%) | catalogued as rs1251050905; called by muse, mutect2
- NOXO1 | c.54C>T p.I18= | Silent (SNP) | VAF 38/109 reads (35%) | catalogued as COSV99936935; called by muse, mutect2, varscan2
- OR9Q1 | c.342C>G p.L114= | Silent (SNP) | VAF 34/79 reads (43%) | catalogued as COSV59039895; called by muse, mutect2, varscan2
- OSR1 | c.156G>C p.L52= | Silent (SNP) | VAF 12/23 reads (52%) | catalogued as rs1456645812, COSV99693499; called by muse, mutect2, varscan2
- OXGR1 | c.387C>T p.I129= | Silent (SNP) | VAF 19/24 reads (79%) | catalogued as rs781565077, COSV100036851; called by muse, mutect2, varscan2
- PITX1 | c.627G>A p.S209= | Silent (SNP) | VAF 11/20 reads (55%) | catalogued as COSV99530461; called by muse, mutect2, varscan2
- POU6F2 | c.1221G>A p.K407= | Silent (SNP) | VAF 10/23 reads (43%) | catalogued as COSV101302340; called by muse, mutect2, varscan2
- RYR2 | c.759T>G p.G253= | Silent (SNP) | VAF 51/113 reads (45%) | catalogued as COSV100767220; called by muse, mutect2, varscan2
- SH2D3C | c.750C>G p.G250= (on ENST00000314830 / NM_170600.3; = p.G93= on NM_005489.4) | Silent (SNP) | VAF 14/15 reads (93%) | catalogued as COSV100136225; called by muse, varscan2
- SLC44A2 | c.1803C>T p.L601= | Silent (SNP) | VAF 27/42 reads (64%) | catalogued as rs1330882999, COSV100212900; called by muse, mutect2, varscan2
- TMPRSS2 | c.138G>A p.P46= | Silent (SNP) | VAF 7/9 reads (78%) | catalogued as rs370092773; called by muse, mutect2, varscan2
- TTN | c.28923C>T p.L9641= (on ENST00000591111; = p.L8714= on NM_133378.4 and 1 other RefSeq transcript) | Silent (SNP) | VAF 38/106 reads (36%) | catalogued as rs972874110, COSV59986559, COSV60202278; called by muse, mutect2, varscan2
- WDHD1 | c.2421A>C p.I807= | Silent (SNP) | VAF 18/56 reads (32%) | catalogued as COSV100777523; called by muse, mutect2, varscan2
- ZBTB38 | c.2436C>G p.T812= | Silent (SNP) | VAF 4/21 reads (19%) | catalogued as COSV100375168; called by muse, mutect2, varscan2
- ZNF425 | c.660C>T p.Y220= | Silent (SNP) | VAF 9/32 reads (28%) | catalogued as COSV100955349; called by muse, mutect2, varscan2
- NUDCD3 | c.509+16868G>T | Intron (SNP) | VAF 31/88 reads (35%) | called by muse, mutect2, varscan2
- SNORD115-8 | n.14G>C | RNA (SNP) | VAF 21/33 reads (64%) | called by muse, mutect2, varscan2
- TMEM273 | c.*2T>A | 3'UTR (SNP) | VAF 11/18 reads (61%) | catalogued as COSV100939562; called by muse, mutect2, varscan2
